Somatic mutation profile of tumor specimen TARGET-30-PARBLH-01A (aliquot TARGET-30-PARBLH-01A-01D) from TARGET case TARGET-30-PARBLH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.7 years (1,360 days).
Specimen TARGET-30-PARBLH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e08b2b45-e473-43ab-a827-baecd2bf860f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARBLH-10A (Blood Derived Normal), aliquot TARGET-30-PARBLH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/279359a0-179e-4df3-a96b-3b592cf3b725

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs192770256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNMD | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65033611; called by muse, mutect2, varscan2
- EXOSC7 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1006474986, COSV55557266; called by muse, mutect2, varscan2
- IFIH1 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV55128452; called by muse, mutect2, varscan2
- KMT2E | c.3397T>A p.F1133I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV57576560, COSV57576758; called by muse, mutect2, varscan2
- MTMR10 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58728955; called by muse, mutect2, varscan2
- NLRP8 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52590781; called by muse, mutect2, varscan2
- OR52K1 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV56904234; called by muse, mutect2, varscan2
- PMFBP1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781341509, COSV52821009, COSV52828160; called by muse, mutect2, varscan2
- CDH24 | c.2130_2155del p.P712Rfs*174 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by pindel, varscan2
- BNIP2 | c.12G>T p.V4= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV51107180, COSV51108012; called by muse, mutect2, varscan2
- CRIM1 | c.318G>C p.A106= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1252055930, COSV54868700; called by muse, mutect2, varscan2
- MLLT1 | c.333C>T p.N111= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as COSV53131886; called by muse, varscan2
